Somatic mutation profile of tumor specimen TCGA-GN-A8LN-01A (aliquot TCGA-GN-A8LN-01A-11D-A372-08) from TCGA case TCGA-GN-A8LN, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 68.2 years (24,896 days).
Specimen TCGA-GN-A8LN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e2fa755-4ec3-42c7-80f5-394f62a421b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GN-A8LN-10A (Blood Derived Normal), aliquot TCGA-GN-A8LN-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3241cb6-18a6-48b3-abe1-8db46af0c31c

The open-access MAF lists 311 somatic variants for this specimen: 212 protein-altering or splice-affecting, 90 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 191, Silent 90, Nonsense Mutation 16, Intron 5, Splice Site 3, RNA 2, 5'UTR 1, Frame Shift Del 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRD7 | c.1834C>T p.R612* | Nonsense Mutation (SNP) | VAF 56/136 reads (41%) | catalogued as rs796065051, COSV54264750; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CYP17A1 | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104894142, CM033602, COSV100882157; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 108/236 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RAC1 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 113/280 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as rs1057519874, COSV61821563, COSV61823187; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ACHE | c.1450T>C p.F484L | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99574677; called by muse, mutect2, varscan2
- ACTN3 | c.1219C>T p.Q407* | Nonsense Mutation (SNP) | VAF 18/51 reads (35%) | catalogued as rs1328219808, COSV101557915; called by muse, mutect2, varscan2
- ADAMTS19 | c.2984C>T p.S995L | Missense Mutation (SNP) | VAF 36/47 reads (77%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV99183987; called by muse, mutect2, varscan2
- ADGRV1 | c.2548C>T p.P850S | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101316673; called by muse, mutect2, varscan2
- ADNP2 | c.1324C>T p.R442W | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs757754593, COSV100080768; called by muse, mutect2, varscan2
- ANK3 | c.3221A>T p.E1074V (on ENST00000280772 / NM_001320874.2; = p.E208V on NM_001149.3) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99782946; called by muse, mutect2, varscan2
- ANKRD34B | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV100103681; called by muse, mutect2, varscan2
- APCDD1L | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 56/114 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs78418340, COSV100954124; called by muse, mutect2, varscan2
- ARAF | c.976C>T p.R326* | Nonsense Mutation (SNP) | VAF 25/26 reads (96%) | catalogued as rs1452639448, COSV99283501; called by muse, mutect2, varscan2
- ARHGAP35 | c.3887A>C p.Q1296P | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as COSV101351885; called by muse, mutect2, varscan2
- ASMT | c.862G>A p.E288K (on ENST00000381229; = p.E316K on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/81 reads (78%) | SIFT deleterious (0.04); PolyPhen benign (0.422); catalogued as COSV101172569; called by muse, mutect2, varscan2
- B4GALT4 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.888); catalogued as COSV100785861; called by muse, mutect2, varscan2
- BAHCC1 | c.6512C>T p.P2171L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1555659121, COSV57031188; called by mutect2, varscan2
- BAHD1 | c.473A>C p.D158A | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT tolerated (0.48); PolyPhen benign (0.039); catalogued as COSV101346809; called by muse, mutect2, varscan2
- BRWD1 | c.2806G>A p.E936K | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.355); catalogued as COSV100314344; called by muse, mutect2, varscan2
- BTN1A1 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as rs1162501561, COSV99764608; called by muse, mutect2, varscan2
- BTN1A1 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV99764611; called by muse, mutect2, varscan2
- C17orf97 | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV100789401; called by muse, varscan2
- CACNA1A | c.4888C>T p.R1630C | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs747020168, COSV100802605, COSV64199885; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1E | c.6254G>A p.R2085Q (on ENST00000367573 / NM_001205293.3; = p.R2042Q on NM_000721.4) | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as COSV62403523; called by muse, mutect2, varscan2
- CACNA1I | c.5978C>T p.S1993F | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.691); catalogued as COSV100361823; called by muse, mutect2, varscan2
- CAPS2 | c.1070G>A p.G357E | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100158344; called by muse, mutect2, varscan2
- CASZ1 | c.2372C>T p.S791F | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.155); catalogued as rs990217717, COSV100682314; called by muse, mutect2
- CCN6 | c.511G>A p.G171R | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV100037250; called by muse, mutect2
- CCT6A | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV99303841; called by muse, mutect2
- CD5L | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.61); PolyPhen benign (0.387); catalogued as rs749437803, COSV100941234; called by muse, mutect2, varscan2
- CDH8 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 64/139 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV100183803, COSV54849644; called by muse, mutect2, varscan2
- CDRT1 | c.1016G>A p.G339E | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as rs746043687, COSV55413444, COSV55413469; called by muse, mutect2, varscan2
- CEACAM20 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as rs181492260, COSV57601759; called by muse, mutect2, varscan2
- CFAP47 | c.4543G>T p.E1515* | Nonsense Mutation (SNP) | VAF 29/36 reads (81%) | catalogued as COSV100545776, COSV57971660; called by muse, mutect2, varscan2
- CFTR | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 62/156 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as rs397508296, CM920165, COSV50040595, COSV99140566; called by muse, mutect2, varscan2
- CHEK2 | c.673C>T p.P225S (on ENST00000382580 / NM_001005735.2; = p.P182S on NM_007194.4) | Missense Mutation (SNP) | VAF 43/64 reads (67%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.572); catalogued as rs786203973, COSV60427339; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLCA2 | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.133); catalogued as COSV100991779; called by muse, mutect2, varscan2
- CLEC4M | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 59/216 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs80086794, COSV99940872; called by muse, varscan2
- CMYA5 | c.6857G>T p.R2286M | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.2); catalogued as COSV101484452; called by muse, mutect2
- CNTN2 | c.74G>A p.W25* | Nonsense Mutation (SNP) | VAF 28/73 reads (38%) | catalogued as COSV100085608; called by muse, mutect2, varscan2
- COL1A1 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.495); catalogued as COSV56808450; called by muse, mutect2, varscan2
- COL4A5 | c.1067G>A p.G356E | Missense Mutation (SNP) | VAF 105/125 reads (84%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs774398576, COSV60375841; called by muse, mutect2, varscan2
- CRTC3 | c.1733C>T p.P578L | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV99185989; called by muse, mutect2, varscan2
- CRYGC | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.352); catalogued as rs770559969, COSV99965288; called by muse, mutect2, varscan2
- CSMD1 | c.3212C>T p.S1071F (on ENST00000520002; = p.S1070F on NM_033225.6) | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs368592556, COSV59302376; called by muse, mutect2, varscan2
- CSPG4 | c.1804C>T p.P602S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.346); catalogued as COSV100414250; called by muse, mutect2, varscan2
- CTCFL | c.1232G>A p.G411E | Missense Mutation (SNP) | VAF 52/268 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99713498; called by muse, mutect2, varscan2
- DCHS1 | c.8890C>T p.R2964C | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771972771, COSV100197830; called by muse, varscan2
- DGKH | c.3340C>T p.P1114S | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.97); PolyPhen benign (0.005); catalogued as COSV54942241; called by muse, mutect2, varscan2
- DISP2 | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs374277640; called by muse, mutect2
- DMXL2 | c.5192C>T p.A1731V | Missense Mutation (SNP) | VAF 104/360 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99198910; called by muse, mutect2, varscan2
- DNAH8 | c.3204G>A p.M1068I | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs1259181793, COSV59447188; called by muse, mutect2, varscan2
- DPPA2 | c.289C>G p.R97G | Missense Mutation (SNP) | VAF 132/287 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV101524802, COSV72117956; called by muse, mutect2, varscan2
- DSCAM | c.3896G>A p.W1299* | Nonsense Mutation (SNP) | VAF 23/77 reads (30%) | catalogued as COSV101261746; called by muse, mutect2, varscan2
- EGFR | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV99295987; called by muse, mutect2, varscan2
- EGFR | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV99295991; called by muse, mutect2, varscan2
- EHD3 | c.1594A>C p.K532Q | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV100434922; called by muse, mutect2, varscan2
- ELF5 | c.719G>A p.G240E (on ENST00000312319 / NM_198381.2; = p.G230E on NM_001422.4) | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT tolerated (1); PolyPhen possibly damaging (0.806); catalogued as COSV56628771; called by muse, mutect2, varscan2
- EML1 | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 31/40 reads (78%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV99215801; called by muse, mutect2, varscan2
- ERC2 | c.457C>T p.Q153* | Nonsense Mutation (SNP) | VAF 104/267 reads (39%) | catalogued as COSV99891630; called by muse, mutect2, varscan2
- ESPNL | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100547648, COSV100547984; called by muse, mutect2, varscan2
- FAN1 | c.1658C>T p.S553L | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs866686628, COSV62950705; called by muse, mutect2, varscan2
- FAT4 | c.12889C>T p.P4297S | Missense Mutation (SNP) | VAF 57/96 reads (59%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); catalogued as rs1178558076, COSV58713498; called by muse, mutect2, varscan2
- FBLN5 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV50904924; called by muse, mutect2
- FBXO10 | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 48/56 reads (86%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV99447401; called by muse, mutect2, varscan2
- FBXO41 | c.1207G>T p.A403S | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.99); catalogued as rs752335857, COSV99721698; called by muse, varscan2
- FCGBP | c.10841G>T p.R3614L | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.28); catalogued as rs758960656; called by muse, mutect2, varscan2
- FOXH1 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 55/97 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs746265996, COSV56761500; called by muse, mutect2, varscan2
- FOXP2 | c.893C>T p.S298L | Missense Mutation (SNP) | VAF 61/127 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs753643915, COSV100647516; called by muse, mutect2, varscan2
- FREM1 | c.6139G>A p.D2047N | Missense Mutation (SNP) | VAF 57/65 reads (88%) | SIFT tolerated (0.19); PolyPhen benign (0.051); catalogued as rs570797431, CD131585, COSV101085707; called by muse, mutect2, varscan2
- FRMD6 | c.317C>T p.P106L (on ENST00000344768 / NM_001267046.2; = p.P98L on NM_152330.4) | Missense Mutation (SNP) | VAF 76/92 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100656412; called by muse, mutect2, varscan2
- FUT9 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 110/250 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs376205938; called by muse, mutect2, varscan2
- GALNT17 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 124/276 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as rs1243906418, COSV100356766; called by muse, mutect2, varscan2
- GPC6 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 83/196 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100990201, COSV65509540; called by muse, mutect2, varscan2
- GRAMD2A | c.466C>T p.Q156* | Nonsense Mutation (SNP) | VAF 14/64 reads (22%) | catalogued as COSV59032955; called by muse, mutect2, varscan2
- GTSE1 | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 58/185 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.019); catalogued as COSV101483266; called by muse, mutect2, varscan2
- H2AC1 | c.190C>T p.L64F | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.974); catalogued as COSV51237077, COSV99219608; called by muse, mutect2, varscan2
- HEMK1 | c.340C>T p.L114F | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV99231972; called by muse, mutect2, varscan2
- HERC2 | c.6728C>T p.T2243I | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.676); catalogued as COSV55322301; called by muse, mutect2, varscan2
- HESX1 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as rs866039836, COSV99907789; called by muse, mutect2, varscan2
- HSF2 | c.1448T>G p.V483G | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV100869754; called by muse, mutect2
- HYDIN | c.14911A>T p.K4971* | Nonsense Mutation (SNP) | VAF 30/78 reads (38%) | catalogued as COSV101125263; called by muse, mutect2, varscan2
- HYDIN | c.7063G>A p.E2355K | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.217); catalogued as COSV59253270; called by mutect2, varscan2
- IQSEC2 | c.1775C>T p.P592L (on ENST00000642864 / NM_001111125.3; = p.P387L on NM_015075.2) | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1556863262, COSV100945133, COSV64726363; called by muse, mutect2, varscan2
- IQSEC3 | c.1256C>T p.T419M (on ENST00000538872 / NM_001170738.2; = p.T116M on NM_015232.1) | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as rs1555087443, COSV100407812; called by muse, mutect2, varscan2
- IQUB | c.2318G>A p.W773* | Nonsense Mutation (SNP) | VAF 32/66 reads (48%) | catalogued as rs765522980, COSV61239974; called by muse, mutect2, varscan2
- ITGA2B | c.1306C>A p.Q436K | Missense Mutation (SNP) | VAF 52/84 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99288420; called by muse, mutect2, varscan2
- ITGA6 | c.1345T>C p.Y449H (on ENST00000442250; = p.Y410H on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV99906222; called by muse, mutect2, varscan2
- ITPKB | c.2707C>T p.P903S | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.351); catalogued as COSV99685385; called by muse, mutect2, varscan2
- KCNA3 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0.024); catalogued as COSV100871331; called by muse, mutect2, varscan2
- KLHDC7A | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 41/47 reads (87%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV68769220; called by muse, mutect2, varscan2
- KLHL32 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 52/103 reads (50%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.731); catalogued as rs746112818, COSV65111001; called by muse, mutect2, varscan2
- KRT222 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV101229491; called by muse, mutect2, varscan2
- LAMB4 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99226029; called by muse, mutect2, varscan2
- LARP1 | c.1123C>T p.R375C (on ENST00000518297 / NM_033551.3; = p.R298C on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/69 reads (83%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.673); catalogued as rs141480802; called by muse, mutect2, varscan2
- LOXL2 | c.1637-1G>A p.X546_splice | Splice Site (SNP) | VAF 25/77 reads (32%) | catalogued as rs1450563761, COSV101207998; called by muse, mutect2, varscan2
- LRP2 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs753776891, COSV99790690; called by muse, mutect2, varscan2
- LRRC28 | c.758C>T p.T253I | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.282); catalogued as COSV100113942; called by muse, mutect2, varscan2
- LRRC66 | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 61/142 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100603138; called by muse, mutect2, varscan2
- LRRTM3 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63669660; called by muse, mutect2, varscan2
- LTF | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 95/219 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs770748411, COSV99212225; called by muse, mutect2, varscan2
- LUZP2 | c.621A>C p.K207N | Missense Mutation (SNP) | VAF 107/263 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1302260315, COSV61207407; called by muse, mutect2, varscan2
- LUZP4 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 39/45 reads (87%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs150784740, COSV64218711; called by muse, mutect2, varscan2
- MAP2K4 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV100796579, COSV62259576; called by muse, mutect2, varscan2
- MBD5 | c.2731C>T p.P911S | Missense Mutation (SNP) | VAF 86/167 reads (51%) | SIFT tolerated (0.47); PolyPhen benign (0.26); catalogued as rs753274698, COSV68695860; called by muse, mutect2, varscan2
- MED16 | c.1905+1G>A p.X635_splice | Splice Site (SNP) | VAF 34/108 reads (31%) | catalogued as COSV99516431; called by muse, varscan2
- MED16 | c.1788G>A p.M596I | Missense Mutation (SNP) | VAF 60/176 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV99516433; called by muse, varscan2
- MEIS3 | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 43/74 reads (58%) | catalogued as rs778888760, COSV58982785; called by muse, mutect2, varscan2
- MGLL | c.710C>T p.S237F (on ENST00000398104 / NM_001003794.2; = p.S247F on NM_007283.6) | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99412472; called by muse, mutect2, varscan2
- MMAA | c.463G>T p.G155* | Nonsense Mutation (SNP) | VAF 57/152 reads (38%) | catalogued as COSV99850114; called by muse, mutect2, varscan2
- MMP15 | c.1048C>T p.P350S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV99539800; called by muse, mutect2
- MOGAT1 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.627); catalogued as rs775492162, COSV101485125, COSV71479894; called by muse, mutect2, varscan2
- MR1 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.796); catalogued as COSV99294807, COSV99295155; called by muse, mutect2
- MST1R | c.2021C>T p.S674F | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99619964; called by muse, mutect2, varscan2
- MUC16 | c.27256C>T p.P9086S | Missense Mutation (SNP) | VAF 92/159 reads (58%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.047); catalogued as COSV67495725; called by muse, mutect2, varscan2
- MUC17 | c.5540C>T p.S1847L | Missense Mutation (SNP) | VAF 124/310 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.092); catalogued as rs1315933138, COSV60302122; called by muse, mutect2, varscan2
- MYH4 | c.3973G>A p.E1325K | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV99702520; called by muse, mutect2, varscan2
- MYLK2 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as rs1442940292, COSV101044983; called by muse, mutect2, varscan2
- MYOCD | c.1270C>T p.P424S | Missense Mutation (SNP) | VAF 75/134 reads (56%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV58506770; called by muse, mutect2, varscan2
- MYOM2 | c.2452G>A p.D818N | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as rs1489890751, COSV100036363; called by muse, mutect2, varscan2
- NAT2 | c.526C>T p.L176F | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.063); catalogued as COSV99674243; called by muse, mutect2, varscan2
- NCOA2 | c.3505C>T p.R1169C | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs766652202, COSV51218359; called by muse, mutect2, varscan2
- NEXMIF | c.4051C>T p.P1351S | Missense Mutation (SNP) | VAF 59/61 reads (97%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs1569334847, COSV50079716; called by muse, mutect2, varscan2
- NKX3-1 | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV66513055; called by muse, mutect2, varscan2
- NLGN4Y | c.2202G>A p.M734I | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); catalogued as COSV100197227; called by muse, mutect2, varscan2
- NLRP1 | c.3136G>A p.E1046K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV52560172; called by muse, mutect2, varscan2
- NOM1 | c.1709C>T p.P570L | Missense Mutation (SNP) | VAF 99/228 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV99316187; called by muse, mutect2, varscan2
- OBSCN | c.3652G>A p.G1218S | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52759441; called by muse, mutect2, varscan2
- OBSCN | c.20939G>A p.G6980D | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1245514377, COSV100806404; called by muse, mutect2, varscan2
- OR10AD1 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1209237167, COSV100046978; called by muse, mutect2, varscan2
- OR13C3 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 32/34 reads (94%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV101053368; called by muse, mutect2, varscan2
- OR14K1 | c.620C>T p.S207L | Missense Mutation (SNP) | VAF 77/168 reads (46%) | SIFT tolerated (0.66); PolyPhen benign (0.006); catalogued as rs760069791, COSV99315551; called by muse, mutect2, varscan2
- OR2A5 | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 87/186 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as rs149614119, COSV68738535; called by muse, mutect2, varscan2
- OR4P4 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 69/177 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.033); catalogued as COSV58921930; called by muse, mutect2, varscan2
- OR5C1 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 50/58 reads (86%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV101030629; called by muse, mutect2, varscan2
- OR5M10 | c.895C>T p.L299F | Missense Mutation (SNP) | VAF 16/342 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV73242406; called by muse, mutect2
- PACSIN1 | c.1225+1G>A p.X409_splice | Splice Site (SNP) | VAF 37/109 reads (34%) | catalogued as rs1327654245, COSV99763415; called by muse, mutect2, varscan2
- PARP12 | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.804); catalogued as COSV99694330; called by muse, mutect2, varscan2
- PCDHA10 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 67/192 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.463); catalogued as COSV100255759, COSV100256484; called by muse, mutect2, varscan2
- PCDHA3 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 67/115 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.16); catalogued as COSV63539394; called by muse, mutect2, varscan2
- PCDHB14 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 9/218 reads (4%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.021); catalogued as COSV99506386; called by muse, mutect2
- PDZD9 | c.263G>A p.R88Q (on ENST00000424898 / NM_001363519.1; = p.R28Q on NM_173806.4) | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.484); catalogued as rs375973948; called by muse, mutect2, varscan2
- PHIP | c.3685C>T p.R1229* | Nonsense Mutation (SNP) | VAF 92/211 reads (44%) | catalogued as COSV99243504; called by muse, mutect2, varscan2
- PIWIL4 | c.648G>C p.K216N | Missense Mutation (SNP) | VAF 120/279 reads (43%) | SIFT tolerated (0.62); PolyPhen benign (0.009); catalogued as COSV100133488; called by muse, mutect2, varscan2
- PLEKHG4B | c.848C>G p.S283C (on ENST00000283426; = p.S639C on NM_052909.5) | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV52044353, COSV99361293; called by muse, mutect2, varscan2
- PLEKHM1 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1251964349, COSV69598825; called by muse, mutect2, varscan2
- PLIN4 | c.3280G>A p.E1094K (on ENST00000301286; = p.E1109K on NM_001367868.2) | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as rs75239962, COSV100014371; called by mutect2, varscan2
- PRDM2 | c.3632G>A p.R1211Q | Missense Mutation (SNP) | VAF 98/118 reads (83%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as rs761459863, COSV52449248; called by muse, mutect2, varscan2
- PROKR2 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 61/115 reads (53%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.622); catalogued as COSV54085543; called by muse, mutect2, varscan2
- PSG11 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 125/331 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV100106296; called by muse, mutect2, varscan2
- PXDNL | c.4316C>T p.P1439L | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as rs1345639960, COSV100685712, COSV100687045; called by muse, mutect2, varscan2
- PZP | c.3482C>T p.S1161F | Missense Mutation (SNP) | VAF 59/114 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV54360896; called by muse, mutect2, varscan2
- RMND1 | c.40C>T p.H14Y | Missense Mutation (SNP) | VAF 23/30 reads (77%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100323831; called by muse, mutect2, varscan2
- RP1 | c.1901C>T p.A634V | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs1372688692, COSV99609176; called by muse, mutect2, varscan2
- RPS6KB1 | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.329); catalogued as rs1232388015, COSV99847830; called by muse, mutect2, varscan2
- RPS6KC1 | c.425C>G p.A142G | Missense Mutation (SNP) | VAF 93/235 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV100874137; called by muse, mutect2, varscan2
- RUNDC3B | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.88); PolyPhen benign (0.027); catalogued as COSV100407381; called by muse, mutect2, varscan2
- RYR1 | c.6836C>T p.S2279F | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100617292; called by muse, mutect2, varscan2
- RYR2 | c.6976C>T p.R2326W | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1207293121, COSV63688225; called by muse, mutect2, varscan2
- SAMD7 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 78/210 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.033); catalogued as COSV59417066; called by muse, varscan2
- SCIN | c.1744G>A p.E582K (on ENST00000297029 / NM_001112706.3; = p.E335K on NM_033128.3) | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867457266, COSV99765408; called by muse, mutect2, varscan2
- SCN10A | c.5365G>A p.D1789N | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs375735101; called by muse, mutect2, varscan2
- SCN9A | c.2764C>T p.R922C (on ENST00000303354; = p.R911C on NM_002977.3) | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774848595, COSV100312528, COSV57608654; ClinVar: uncertain significance; called by muse, mutect2
- SDK1 | c.1670A>G p.N557S | Missense Mutation (SNP) | VAF 71/171 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs371807433; called by muse, mutect2, varscan2
- SEC63 | c.1624C>T p.P542S | Missense Mutation (SNP) | VAF 86/205 reads (42%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100938491; called by muse, mutect2, varscan2
- SEMA3F | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs772183288, COSV99137190; called by muse, mutect2, varscan2
- SEMA3G | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV51594116; called by muse, mutect2, varscan2
- SHLD2 | c.2435C>T p.P812L | Missense Mutation (SNP) | VAF 59/111 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100079646; called by muse, mutect2, varscan2
- SLC25A38 | c.355C>T p.H119Y | Missense Mutation (SNP) | VAF 15/411 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.117); catalogued as COSV56194495; called by muse, mutect2
- SLC26A2 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 65/81 reads (80%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV99640447; called by muse, mutect2, varscan2
- SLC4A1 | c.2484G>A p.V828= | Splice Region (SNP) | VAF 11/56 reads (20%) | catalogued as COSV99293760; called by muse, mutect2, varscan2
- SLC6A13 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758728968, COSV58260973; called by muse, mutect2, varscan2
- SLITRK3 | c.1756G>A p.V586I | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.344); catalogued as COSV99580358; called by muse, mutect2, varscan2
- SPAG17 | c.2945C>T p.S982F | Missense Mutation (SNP) | VAF 150/384 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.114); catalogued as COSV100310940; called by muse, mutect2, varscan2
- SPTA1 | c.5191G>T p.E1731* | Nonsense Mutation (SNP) | VAF 53/154 reads (34%) | catalogued as COSV100935760, COSV63757183; called by muse, mutect2, varscan2
- SPTA1 | c.5190G>T p.E1730D | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV100935761, COSV63748741; called by muse, mutect2, varscan2
- STING1 | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs1167476128, COSV58172652; called by muse, mutect2
- SYT14 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as COSV55063157; called by muse, mutect2, varscan2
- TBC1D32 | c.2453C>T p.S818F | Missense Mutation (SNP) | VAF 47/61 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV51536083, COSV51554832; called by muse, mutect2, varscan2
- TENM1 | c.784C>A p.L262M | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100951238; called by muse, mutect2, varscan2
- TLR7 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 48/53 reads (91%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.787); catalogued as rs868177091, COSV66124215; called by muse, mutect2, varscan2
- TMC5 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 148/384 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs1211823418, COSV66865296; called by muse, mutect2, varscan2
- TNFRSF11A | c.1378C>T p.L460F | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs758469956, COSV99500685; called by muse, mutect2, varscan2
- TNS4 | c.530G>A p.G177D | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.543); catalogued as COSV54189251; called by muse, mutect2, varscan2
- TNXB | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV64478324; called by muse, mutect2, varscan2
- TRMT44 | c.1813C>A p.P605T | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs779176903, COSV101077878; called by muse, mutect2, varscan2
- TTBK2 | c.3542C>T p.S1181L | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.788); catalogued as rs748766632, COSV51157748; called by muse, mutect2, varscan2
- TTN | c.44743G>A p.G14915R (on ENST00000591111; = p.G7491R on NM_003319.4) | Missense Mutation (SNP) | VAF 52/92 reads (57%) | PolyPhen probably damaging (1); catalogued as rs1193616870, COSV100623416, COSV100634849; called by muse, mutect2, varscan2
- TTN | c.34300G>A p.E11434K (on ENST00000591111; = p.E12497K on NM_001267550.2) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | PolyPhen benign (0); catalogued as rs1553781387, COSV100634853; ClinVar: uncertain significance; called by mutect2, varscan2
- TTN | c.33386C>T p.P11129L (on ENST00000591111; = p.P10202L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | PolyPhen benign (0.001); catalogued as rs1317463047, COSV100634854; called by muse, mutect2, varscan2
- TUBA3C | c.1097G>A p.G366E | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.957); catalogued as rs868127144, COSV68029500; called by muse, mutect2, varscan2
- UGT2B15 | c.753G>A p.M251I | Missense Mutation (SNP) | VAF 102/227 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.378); catalogued as COSV57733899; called by muse, mutect2, varscan2
- UMOD | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 66/165 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.141); catalogued as COSV100208781; called by muse, mutect2, varscan2
- UNC13A | c.3395C>T p.P1132L | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as COSV53187050, COSV99409606; called by muse, mutect2
- USHBP1 | c.1495C>T p.R499W | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs750844210, COSV53104784; called by muse, mutect2, varscan2
- USP50 | c.685C>T p.R229W (on ENST00000616326; = p.R220W on NM_203494.5) | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as rs757821322, COSV101597741; called by muse, mutect2, varscan2
- VPS35 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 122/291 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.16); catalogued as COSV54477006; called by muse, mutect2, varscan2
- WDR44 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 120/131 reads (92%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99562050; called by muse, mutect2, varscan2
- WNK1 | c.4234G>C p.V1412L (on ENST00000315939 / NM_018979.4; = p.V1165L on NM_014823.3) | Missense Mutation (SNP) | VAF 66/139 reads (47%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV100268898, COSV100268981; called by muse, mutect2, varscan2
- XIRP2 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99748777; called by muse, mutect2, varscan2
- XPOT | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs765498017, COSV60346572; called by muse, mutect2, varscan2
- XYLT1 | c.2077G>A p.D693N | Missense Mutation (SNP) | VAF 67/157 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54479461; called by muse, mutect2, varscan2
- YIPF7 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.409); catalogued as rs1269245063, COSV100274715; called by muse, mutect2, varscan2
- ZC3H18 | c.2035C>T p.P679S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs116598906, COSV99964561; called by muse, mutect2, varscan2
- ZC3HC1 | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1234345268, COSV100316140; called by muse, mutect2, varscan2
- ZMIZ1 | c.1857G>C p.Q619H | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV100566657; called by muse, mutect2, varscan2
- ZNF334 | c.1894C>T p.Q632* | Nonsense Mutation (SNP) | VAF 50/246 reads (20%) | catalogued as COSV100749241; called by muse, mutect2, varscan2
- ZNF423 | c.1624G>A p.E542K (on ENST00000563137 / NM_001379286.1; = p.E534K on NM_015069.4) | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as rs749382074, COSV52175690, COSV52176832; called by muse, mutect2, varscan2
- ZNF530 | c.1412C>T p.S471L | Missense Mutation (SNP) | VAF 61/172 reads (35%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.965); catalogued as COSV60532218; called by muse, mutect2, varscan2
- ZNF761 | c.13C>T p.Q5* | Nonsense Mutation (SNP) | VAF 38/85 reads (45%) | catalogued as rs202160147, COSV100483521; called by muse, mutect2, varscan2
- ADAMTSL2 | c.1979C>T p.S660F | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- WDR59 | c.2781del p.H928Tfs*12 | Frame Shift Del (DEL) | VAF 26/74 reads (35%) | called by mutect2, pindel, varscan2
- ADAM7 | c.1506G>A p.G502= | Silent (SNP) | VAF 82/161 reads (51%) | catalogued as COSV99445115; called by muse, mutect2, varscan2
- AKAP13 | c.3843C>T p.S1281= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as rs761455307, COSV100774875; called by muse, mutect2, varscan2
- AKAP13 | c.4113G>A p.G1371= | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as COSV100774876; called by muse, mutect2, varscan2
- ALOX5 | c.801G>A p.L267= | Silent (SNP) | VAF 34/48 reads (71%) | catalogued as COSV100980226; called by muse, mutect2, varscan2
- AMBP | c.522C>T p.I174= | Silent (SNP) | VAF 19/29 reads (66%) | catalogued as COSV99469460; called by muse, mutect2, varscan2
- AMPD2 | c.2118C>T p.S706= | Silent (SNP) | VAF 70/173 reads (40%) | catalogued as COSV99858218; called by muse, mutect2, varscan2
- ANO1 | c.1839G>A p.L613= | Silent (SNP) | VAF 40/109 reads (37%) | catalogued as rs776353827, COSV60284327, COSV60288810; called by muse, mutect2, varscan2
- APPL1 | c.906C>T p.Y302= | Silent (SNP) | VAF 55/133 reads (41%) | catalogued as COSV99898129; called by muse, mutect2, varscan2
- BTK | c.1539G>A p.E513= | Silent (SNP) | VAF 101/114 reads (89%) | catalogued as rs192689502, COSV58124673; called by muse, mutect2, varscan2
- CAPN13 | c.12C>T p.Y4= | Silent (SNP) | VAF 12/19 reads (63%) | catalogued as rs1249691977, COSV99701267; called by muse, mutect2, varscan2
- CARD9 | c.975C>T p.F325= | Silent (SNP) | VAF 27/40 reads (68%) | catalogued as rs769988935, COSV100261420; called by muse, mutect2, varscan2
- CCKAR | c.360C>T p.F120= | Silent (SNP) | VAF 55/139 reads (40%) | catalogued as COSV99810620; called by muse, mutect2, varscan2
- CDC42EP2 | c.111C>T p.F37= | Silent (SNP) | VAF 45/96 reads (47%) | catalogued as COSV99659119, COSV99659224; called by muse, mutect2, varscan2
- CFAP47 | c.4542G>A p.K1514= | Silent (SNP) | VAF 31/38 reads (82%) | catalogued as COSV100545775, COSV57973710; called by muse, mutect2, varscan2
- CNTNAP5 | c.957G>A p.G319= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV101444372; called by muse, mutect2, varscan2
- COL2A1 | c.2025T>G p.G675= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV100477794; called by muse, mutect2, varscan2
- DCHS1 | c.8889C>T p.A2963= | Silent (SNP) | VAF 7/9 reads (78%) | catalogued as rs1300684682, COSV100197833; called by muse, mutect2, varscan2
- DMGDH | c.708G>A p.Q236= | Silent (SNP) | VAF 54/196 reads (28%) | catalogued as rs1033748869, COSV99669635; called by muse, mutect2, varscan2
- DMXL1 | c.4926T>C p.F1642= | Silent (SNP) | VAF 7/116 reads (6%) | catalogued as COSV100225236; called by muse, mutect2
- EFR3A | c.2452C>T p.L818= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs1182684251, COSV99603742; called by muse, mutect2, varscan2
- EHD3 | c.1593G>A p.R531= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as rs267599346, COSV100434921; called by muse, mutect2, varscan2
- FABP2 | c.381G>A p.R127= | Silent (SNP) | VAF 84/188 reads (45%) | catalogued as rs1463853237, COSV99917035; called by muse, mutect2, varscan2
- FAM83B | c.195G>A p.L65= | Silent (SNP) | VAF 65/153 reads (42%) | catalogued as COSV60924789; called by muse, mutect2, varscan2
- FLT4 | c.3027G>A p.L1009= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV99989453; called by muse, mutect2, varscan2
- FRMD4B | c.258C>T p.D86= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as COSV101273685; called by muse, mutect2, varscan2
- GAL3ST3 | c.591C>T p.F197= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as rs1427921003, COSV61748771; called by muse, mutect2, varscan2
- GLRA3 | c.1038A>G p.E346= | Silent (SNP) | VAF 51/119 reads (43%) | catalogued as COSV99928335; called by muse, mutect2, varscan2
- GOLGB1 | c.6459C>T p.V2153= | Silent (SNP) | VAF 120/263 reads (46%) | catalogued as rs773719193, COSV100511661; called by muse, mutect2, varscan2
- H2BC4 | c.276C>T p.S92= | Silent (SNP) | VAF 60/160 reads (38%) | catalogued as rs761241511, COSV100020133; called by muse, mutect2, varscan2
- HAND2 | c.567G>A p.L189= | Silent (SNP) | VAF 41/130 reads (32%) | catalogued as COSV100854265, COSV64018546; called by muse, mutect2, varscan2
- HECW1 | c.267C>T p.S89= | Silent (SNP) | VAF 42/85 reads (49%) | catalogued as rs758391305, COSV101224403; called by muse, mutect2, varscan2
- HTR1A | c.1268G>A p.*423= | Silent (SNP) | VAF 106/702 reads (15%) | catalogued as COSV100109101; called by muse, mutect2, varscan2
- HYDIN | c.1785C>T p.I595= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV99865975; called by muse, mutect2, varscan2
- INSC | c.381G>A p.R127= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs1327896541, COSV101089791; called by muse, mutect2, varscan2
- KAT6A | c.1575C>T p.S525= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as COSV55907066; called by muse, mutect2, varscan2
- KCNH2 | c.2070C>T p.P690= | Silent (SNP) | VAF 27/56 reads (48%) | catalogued as COSV100061343; called by muse, mutect2, varscan2
- KLHL22 | c.1050C>T p.F350= | Silent (SNP) | VAF 49/118 reads (42%) | catalogued as rs774571360, COSV61020354; called by muse, mutect2, varscan2
- KMT2E | c.4842C>T p.N1614= | Silent (SNP) | VAF 32/106 reads (30%) | catalogued as COSV57573149, COSV99997183; called by muse, mutect2, varscan2
- MCOLN3 | c.666G>A p.L222= | Silent (SNP) | VAF 99/249 reads (40%) | catalogued as COSV100353103; called by muse, mutect2, varscan2
- MFAP5 | c.261G>A p.E87= | Silent (SNP) | VAF 74/158 reads (47%) | catalogued as COSV63945121, COSV63945125; called by muse, mutect2, varscan2
- MPP6 | c.72C>T p.F24= | Silent (SNP) | VAF 46/110 reads (42%) | catalogued as COSV56038507; called by muse, mutect2, varscan2
- MTUS2 | c.1506C>T p.V502= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as rs578164574, COSV101462411; called by muse, mutect2, varscan2
- MUC16 | c.37656C>A p.I12552= | Silent (SNP) | VAF 160/248 reads (65%) | catalogued as COSV101202156; called by muse, mutect2, varscan2
- MYH2 | c.1509G>A p.E503= | Silent (SNP) | VAF 97/173 reads (56%) | catalogued as COSV55440425, COSV55448177; called by muse, mutect2, varscan2
- MYO18B | c.2634C>T p.I878= | Silent (SNP) | VAF 108/251 reads (43%) | catalogued as rs866173516, COSV59135803; called by muse, mutect2
- MYOCD | c.249C>T p.L83= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs1376028716, COSV58503787; called by muse, mutect2
- NEXMIF | c.2142G>A p.R714= | Silent (SNP) | VAF 70/78 reads (90%) | catalogued as COSV50070884; called by muse, mutect2, varscan2
- NLRP5 | c.2202G>A p.R734= | Silent (SNP) | VAF 95/204 reads (47%) | catalogued as rs760106199, COSV66763366; called by muse, mutect2, varscan2
- NMNAT3 | c.571C>T p.L191= (on ENST00000296202 / NM_001320512.1; = p.L154= on NM_178177.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/78 reads (45%) | catalogued as COSV56156885, COSV99951627; called by muse, mutect2, varscan2
- NRL | c.231C>T p.T77= | Silent (SNP) | VAF 24/28 reads (86%) | catalogued as rs1239961148, COSV99393887; called by muse, mutect2, varscan2
- OR13G1 | c.75C>T p.F25= | Silent (SNP) | VAF 35/87 reads (40%) | catalogued as COSV62943642; called by muse, mutect2, varscan2
- OR2F2 | c.765G>A p.T255= | Silent (SNP) | VAF 45/109 reads (41%) | catalogued as rs866839513, COSV68832568; called by muse, mutect2, varscan2
- OR7E24 | c.81C>T p.V27= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV71702175; called by muse, mutect2
- PACS1 | c.942C>T p.T314= | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as COSV100269584, COSV100270753; called by muse, mutect2, varscan2
- PANK4 | c.501C>T p.F167= | Silent (SNP) | VAF 36/80 reads (45%) | catalogued as rs773473532, COSV101022588; called by muse, mutect2, varscan2
- PCDH11X | c.3318G>A p.G1106= | Silent (SNP) | VAF 27/31 reads (87%) | catalogued as COSV100012284; called by muse, mutect2, varscan2
- PCDHB8 | c.1683C>T p.F561= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as rs782576597, COSV50802007; called by muse, mutect2, varscan2
- PCDHGA9 | c.2001C>T p.S667= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as COSV99549102; called by muse, mutect2, varscan2
- PHLDB2 | c.2370G>A p.K790= (on ENST00000393925 / NM_001134439.2; = p.K747= on NM_145753.2) | Silent (SNP) | VAF 24/43 reads (56%) | catalogued as COSV101208781; called by muse, mutect2, varscan2
- PLXNA4 | c.972G>A p.R324= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as COSV100327896; called by muse, mutect2, varscan2
- PPP3R2 | c.507C>T p.I169= | Silent (SNP) | VAF 47/58 reads (81%) | catalogued as rs752505094, COSV62452542; called by muse, mutect2, varscan2
- PRDM14 | c.1401G>A p.G467= | Silent (SNP) | VAF 36/81 reads (44%) | catalogued as COSV99400608; called by muse, mutect2
- PRF1 | c.177C>T p.F59= | Silent (SNP) | VAF 28/47 reads (60%) | catalogued as rs1184024036, COSV100942703; called by muse, mutect2, varscan2
- PTH | c.144G>A p.S48= | Silent (SNP) | VAF 55/206 reads (27%) | catalogued as rs376145884; called by muse, mutect2, varscan2
- PTPN23 | c.2442C>T p.P814= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs569455227, COSV99651149; called by muse, varscan2
- PTPRT | c.549G>A p.R183= | Silent (SNP) | VAF 29/111 reads (26%) | catalogued as COSV100631252; called by muse, mutect2, varscan2
- RAB34 | c.636G>A p.V212= | Silent (SNP) | VAF 5/75 reads (7%) | catalogued as COSV99973201; called by muse, mutect2
- RAP1GAP2 | c.1233C>T p.T411= | Silent (SNP) | VAF 71/226 reads (31%) | catalogued as COSV99624670; called by muse, mutect2, varscan2
- SCN10A | c.1071C>T p.S357= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as COSV101479583; called by muse, mutect2, varscan2
- SDR42E1 | c.1181G>A p.*394= | Silent (SNP) | VAF 32/61 reads (52%) | catalogued as COSV61094179; called by muse, mutect2, varscan2
- SFMBT2 | c.2097C>T p.F699= | Silent (SNP) | VAF 20/37 reads (54%) | catalogued as rs868755634, COSV62805606; called by muse, mutect2, varscan2
- SH3PXD2B | c.303C>T p.Y101= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as COSV100288636; called by muse, mutect2, varscan2
- SLC17A1 | c.651C>T p.F217= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as rs1286940443, COSV55081088; called by muse, mutect2, varscan2
- SLC2A7 | c.246C>T p.S82= | Silent (SNP) | VAF 90/113 reads (80%) | catalogued as COSV101280845; called by muse, mutect2, varscan2
- SLC5A7 | c.1489C>T p.L497= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as COSV50888880, COSV99887400; called by muse, mutect2
- SMR3A | c.357C>T p.F119= | Silent (SNP) | VAF 30/90 reads (33%) | catalogued as COSV56949864; called by muse, mutect2, varscan2
- SOAT1 | c.1089C>T p.V363= | Silent (SNP) | VAF 61/181 reads (34%) | catalogued as COSV100859114; called by muse, mutect2, varscan2
- SORCS3 | c.3207G>A p.R1069= | Silent (SNP) | VAF 27/58 reads (47%) | catalogued as COSV100865724; called by muse, mutect2, varscan2
- SPHKAP | c.2493G>A p.K831= | Silent (SNP) | VAF 24/489 reads (5%) | catalogued as COSV100764599; called by muse, mutect2
- SPRY4 | c.15C>T p.I5= (on ENST00000434127 / NM_001127496.3; = p.I28= on NM_030964.4) | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV100702252; called by muse, mutect2, varscan2
- SRGAP3 | c.1860C>T p.L620= | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as rs748427822, COSV64534253; ClinVar: likely benign; called by muse, mutect2, varscan2
- STAB1 | c.2355C>T p.G785= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV100402426; called by muse, mutect2, varscan2
- SYT1 | c.258A>G p.K86= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as COSV99697748; called by muse, mutect2, varscan2
- TM4SF4 | c.564G>A p.G188= | Silent (SNP) | VAF 39/91 reads (43%) | catalogued as rs756509127, COSV59515133; called by muse, mutect2, varscan2
- TMEM98 | c.535C>T p.L179= | Silent (SNP) | VAF 63/107 reads (59%) | catalogued as COSV99912950; called by muse, mutect2, varscan2
- TRIM10 | c.267C>T p.S89= | Silent (SNP) | VAF 73/177 reads (41%) | catalogued as rs147578020; called by muse, mutect2, varscan2
- TRIT1 | c.912C>T p.N304= | Silent (SNP) | VAF 83/198 reads (42%) | catalogued as rs778548439, COSV100381761, COSV57548950; called by muse, mutect2, varscan2
- TXNRD1 | c.639T>C p.G213= (on ENST00000525566 / NM_001093771.3; = p.G115= on NM_003330.4) | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as COSV100723615; called by muse, mutect2, varscan2
- ZDBF2 | c.2586G>A p.R862= | Silent (SNP) | VAF 4/74 reads (5%) | catalogued as COSV100985690, COSV65624953; called by muse, mutect2
- ZNF71 | c.186C>T p.P62= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as rs749107337, COSV100046427; called by muse, varscan2
- AP001042.1 | n.2333G>A | RNA (SNP) | VAF 42/136 reads (31%) | called by muse, mutect2, varscan2
- CFH | c.-1A>T | 5'UTR (SNP) | VAF 25/84 reads (30%) | catalogued as COSV100661691; called by muse, mutect2, varscan2
- FBXL13 | c.496-5553G>A | Intron (SNP) | VAF 21/83 reads (25%) | catalogued as COSV100502276; called by muse, mutect2, varscan2
- FBXL13 | c.496-5554G>A | Intron (SNP) | VAF 21/81 reads (26%) | catalogued as COSV100502277; called by muse, mutect2, varscan2
- FRMPD2B | n.696C>T | RNA (SNP) | VAF 129/425 reads (30%) | catalogued as rs1245401559; called by muse, mutect2, varscan2
- MATK | chr19:3789331 G>A | 5'Flank (SNP) | VAF 12/32 reads (38%) | catalogued as COSV100036352; called by muse, mutect2, varscan2
- MGST3 | c.-104+967G>A | Intron (SNP) | VAF 32/84 reads (38%) | catalogued as rs377067925; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-23916G>A | Intron (SNP) | VAF 75/160 reads (47%) | catalogued as rs267603417, COSV101045344; called by muse, mutect2, varscan2
- TTN | c.10360+1438G>A | Intron (SNP) | VAF 37/167 reads (22%) | catalogued as COSV100592363, COSV100634856; called by muse, mutect2, varscan2
